Surgical pathology report (de-identified scan), TCGA case TCGA-UD-AAC7, project TCGA-MESO (Mesothelioma), tissue source site  University of Western Australia, specimen TCGA-UD-AAC7-01A (Primary Tumor).

Pathology Report

Printed

DOB:

Sex: M

Ref. by
Collection Date:

CLINICAL HISTORY:

Pleural effusion and blood ? meso.

MACROSCOPIC:

Lung biopsy: Six tan fragments ranging from 2-5mm (1x6ae,).

MICROSCOPIC:

Sections show a fragment of an infiltrating epithelioid neoplasm. The tumour cells do not produce mucin but some tissue mucin is present. A panel of antibodies shows the following profile;
Keratin broad spectrum (AE1/3); Calretinin and WT-1 all positive.
TTF-1 and CEA (polyclonal): both negative.

CONCLUSION:

Lung biopsy; MALIGNANT MESOTHELIOMA, epithelioid.

Pathologist:

ICD-O-3
Mesothelioma, epithelioid, malignant
Site: Pleura NOS
238.4
9052/3
11/29/14

Confidentiality: This document is confidential. If you are not the intended recipient you must not read, copy, distribute or act in reliance on it. If you have received this document in error please notify us immediately and destroy the original message.

Source: NCI Genomic Data Commons file 515cb229-0af7-46a7-829f-157904c907ca (TCGA-UD-AAC7.2CF5E13F-7B32-4D60-BD15-A50AC112DBEB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).